Somatic mutation profile of tumor specimen TCGA-V4-A9EH-01A (aliquot TCGA-V4-A9EH-01A-11D-A39W-08) from TCGA case TCGA-V4-A9EH, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 53.6 years (19,573 days).
Specimen TCGA-V4-A9EH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f09c5a9d-969e-41f2-b20c-967de3538ebd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9EH-10A (Blood Derived Normal), aliquot TCGA-V4-A9EH-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bc8700c-0d1c-463c-b342-8e036689e7ce

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 25/46 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CCN4 | c.1037G>A p.C346Y | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51532731; called by muse, mutect2, varscan2
- NLRP3 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1033902069, COSV60222719; called by muse, mutect2, varscan2
- SNX20 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs757162450, COSV56056827; called by muse, mutect2, varscan2
- ALDH2 | c.947G>C p.G316A | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MSS51 | c.425G>A p.W142* | Nonsense Mutation (SNP) | VAF 42/100 reads (42%) | called by muse, mutect2, varscan2
- PRAMEF18 | c.212A>G p.K71R | Missense Mutation (SNP) | VAF 42/246 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- SYNE2 | c.19686dup p.I6563Hfs*9 | Frame Shift Ins (INS) | VAF 19/50 reads (38%) | called by mutect2, pindel, varscan2
- FANCD2 | c.4344T>C p.S1448= | Silent (SNP) | VAF 33/74 reads (45%) | called by muse, mutect2, varscan2
- TRIM62 | c.1326C>T p.R442= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as rs746662481; called by muse, mutect2, varscan2
